Somatic mutation profile of tumor specimen TCGA-E7-A85H-01A (aliquot TCGA-E7-A85H-01A-11D-A34U-08) from TCGA case TCGA-E7-A85H, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 64.3 years (23,497 days).
Specimen TCGA-E7-A85H-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c4943326-11ae-4dbd-8d24-8a5062e86dbe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-E7-A85H-10B (Blood Derived Normal), aliquot TCGA-E7-A85H-10B-01D-A34X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2756834d-6372-4640-a5db-2aa5929a2060

The open-access MAF lists 482 somatic variants for this specimen: 369 protein-altering or splice-affecting, 107 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 317, Silent 107, Splice Site 14, Frame Shift Del 12, In Frame Del 7, Nonsense Mutation 7, Splice Region 6, Frame Shift Ins 5, Intron 2, RNA 2, 3'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERCC2 | c.713A>G p.N238S | Missense Mutation (SNP) | VAF 23/37 reads (62%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55538701; called by muse, mutect2, varscan2
- ABCA1 | c.3786A>G p.S1262= | Splice Region (SNP) | VAF 14/66 reads (21%) | catalogued as rs758324023, COSV66066028; called by muse, mutect2, varscan2
- ABITRAM | c.433G>A p.V145I | Missense Mutation (SNP) | VAF 50/74 reads (68%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.598); catalogued as rs1365768211, COSV57702760; called by muse, mutect2, varscan2
- ACOT11 | c.1495G>A p.D499N | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.451); catalogued as COSV56363990; called by muse, mutect2, varscan2
- ACSS3 | c.869C>T p.S290L | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); catalogued as COSV54085632, COSV54097587; called by muse, mutect2, varscan2
- ACTR3 | c.190G>T p.D64Y | Missense Mutation (SNP) | VAF 27/38 reads (71%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV54300783; called by muse, mutect2, varscan2
- ADAM15 | c.1919T>C p.V640A | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.992); catalogued as COSV55126665; called by muse, mutect2, varscan2
- ADAM18 | c.947T>C p.I316T | Missense Mutation (SNP) | VAF 76/289 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.457); catalogued as COSV55847020; called by muse, mutect2, varscan2
- ADAM32 | c.2171C>T p.S724L | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.987); catalogued as rs758758413, COSV65948565; called by muse, mutect2, varscan2
- ADAM9 | c.2302A>G p.I768V | Missense Mutation (SNP) | VAF 9/234 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs772376011, COSV65959906; called by muse, mutect2
- ADAMTS20 | c.1283A>G p.H428R | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV67130964; called by muse, mutect2, varscan2
- ADCY6 | c.2197C>T p.R733C | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.836); catalogued as rs773761749, COSV57167712; called by muse, mutect2, varscan2
- ADGRL3 | c.3653G>A p.S1218N (on ENST00000506720 / NM_001322402.2; = p.S1150N on NM_015236.6) | Missense Mutation (SNP) | VAF 7/132 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); catalogued as rs1013636944, COSV72230478; called by muse, mutect2
- AGRN | c.2515G>A p.D839N | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.495); catalogued as rs148315419; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALB | c.238G>T p.D80Y | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as COSV55737884, COSV55741637; called by muse, mutect2, varscan2
- ALDOA | c.608G>A p.R203H (on ENST00000642816 / NM_001243177.4; = p.R149H on NM_184041.5) | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.061); catalogued as rs762685202, COSV57632641; called by muse, mutect2, varscan2
- ALG10 | c.123C>G p.H41Q | Missense Mutation (SNP) | VAF 89/217 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56792446; called by muse, mutect2, varscan2
- AMIGO3 | c.702G>T p.W234C | Missense Mutation (SNP) | VAF 17/23 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57538449; called by muse, mutect2, varscan2
- ANKRD28 | c.1738A>G p.N580D | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV67517894; called by muse, mutect2, varscan2
- ANKRD55 | c.986del p.P329Lfs*119 | Frame Shift Del (DEL) | VAF 41/236 reads (17%) | catalogued as rs767394252, COSV61949966; called by mutect2, pindel, varscan2
- ANXA6 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100636844; called by muse, mutect2
- ANXA6 | c.4G>T p.A2S | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV100636845; called by muse, mutect2
- APBA1 | c.1199A>G p.D400G | Missense Mutation (SNP) | VAF 41/74 reads (55%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV55227348; called by muse, mutect2, varscan2
- ARFGEF2 | c.2645C>T p.T882I | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.082); catalogued as COSV64212084; called by muse, mutect2, varscan2
- ARSD | c.1358A>G p.H453R | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV99472064; called by muse, mutect2, varscan2
- AS3MT | c.511G>A p.A171T | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.2); catalogued as COSV54916774; called by muse, mutect2, varscan2
- ASH1L | c.3749A>T p.H1250L | Missense Mutation (SNP) | VAF 334/461 reads (72%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); catalogued as COSV64207757; called by muse, mutect2, varscan2
- ATAD2 | c.2539C>G p.R847G | Missense Mutation (SNP) | VAF 51/142 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.05); catalogued as COSV54880131, COSV54880435; called by muse, mutect2, varscan2
- ATAD2 | c.214C>A p.R72S | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.046); catalogued as COSV54880446; called by muse, mutect2, varscan2
- ATM | c.6112C>A p.H2038N | Missense Mutation (SNP) | VAF 20/24 reads (83%) | SIFT deleterious (0); PolyPhen benign (0.39); catalogued as rs1060501643, COSV53742034; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- B3GALT4 | c.814T>A p.S272T | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.401); catalogued as COSV65851522; called by muse, mutect2, varscan2
- BCO2 | c.593T>C p.M198T | Missense Mutation (SNP) | VAF 85/102 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV63063255; called by muse, mutect2, varscan2
- BEND3 | c.1619A>C p.E540A | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as COSV64681005; called by muse, mutect2, varscan2
- C11orf42 | c.211C>T p.R71W | Missense Mutation (SNP) | VAF 42/51 reads (82%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs1192535832, COSV56411180; called by muse, mutect2, varscan2
- C11orf53 | c.271G>A p.G91R | Missense Mutation (SNP) | VAF 110/158 reads (70%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV54721475; called by muse, mutect2, varscan2
- C12orf50 | c.598G>A p.D200N | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.642); catalogued as COSV53895087; called by muse, mutect2, varscan2
- C18orf25 | c.1063T>C p.S355P | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.105); catalogued as COSV56366204; called by muse, mutect2, varscan2
- C2CD3 | c.874C>T p.Q292* | Nonsense Mutation (SNP) | VAF 49/84 reads (58%) | catalogued as COSV100486400; called by muse, mutect2, varscan2
- CCDC102B | c.1523_1524insTTTTT p.R508Sfs*34 | Frame Shift Ins (INS) | VAF 17/88 reads (19%) | catalogued as COSV60140939; called by mutect2, pindel*, varscan2*
- CCNA2 | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.043); catalogued as COSV52655025, COSV99144834; called by muse, mutect2
- CD160 | c.133A>G p.T45A | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52523395; called by muse, mutect2, varscan2
- CD300LF | c.506T>G p.L169R | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV56896917; called by muse, mutect2
- CD86 | c.734A>G p.H245R (on ENST00000330540 / NM_175862.5; = p.H239R on NM_006889.4) | Missense Mutation (SNP) | VAF 89/227 reads (39%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs1410462982, COSV52606668; called by muse, mutect2, varscan2
- CD9 | c.537G>A p.K179= | Splice Region (SNP) | VAF 27/35 reads (77%) | catalogued as COSV50530310; called by muse, mutect2, varscan2
- CD96 | c.166A>G p.M56V | Missense Mutation (SNP) | VAF 77/244 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as COSV51916044; called by muse, mutect2, varscan2
- CDH23 | c.1808C>A p.A603E | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0.01); PolyPhen benign (0.415); catalogued as COSV54933127; called by muse, mutect2, varscan2
- CDK5RAP3 | c.857C>T p.S286F | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.328); catalogued as COSV58114883, COSV58115523; called by muse, mutect2, varscan2
- CEP55 | c.1006T>C p.Y336H | Missense Mutation (SNP) | VAF 48/78 reads (62%) | SIFT tolerated (0.3); PolyPhen benign (0.037); catalogued as rs752455356, COSV65185038; called by muse, mutect2, varscan2
- CERT1 | c.1873-1G>A p.X625_splice (on ENST00000405807 / NM_001130105.1; = p.X497_splice on NM_005713.3) | Splice Site (SNP) | VAF 13/76 reads (17%) | catalogued as COSV99783056; called by muse, mutect2
- CFAP298-TCP10L | c.524C>T p.S175L | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.514); catalogued as rs146867345; called by muse, mutect2, varscan2
- CFAP43 | c.898A>G p.R300G | Missense Mutation (SNP) | VAF 53/86 reads (62%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV53377707; called by muse, mutect2, varscan2
- CFAP44 | c.815C>T p.S272F | Missense Mutation (SNP) | VAF 28/309 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV55611124; called by muse, mutect2
- CFAP57 | c.1420T>C p.C474R | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV63016700; called by muse, mutect2, varscan2
- CHCHD1 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.828); catalogued as COSV65708300; called by muse, mutect2, varscan2
- CLCN2 | c.147del p.W49* | Frame Shift Del (DEL) | VAF 23/92 reads (25%) | catalogued as COSV99659104; called by mutect2, pindel, varscan2
- CLDN22 | c.638C>A p.T213K | Missense Mutation (SNP) | VAF 18/296 reads (6%) | SIFT tolerated (0.93); PolyPhen benign (0.035); catalogued as COSV60109319; called by muse, mutect2
- CLIP4 | c.1642C>T p.P548S | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs762550670, COSV60749032; called by muse, mutect2, varscan2
- CNGA2 | c.1155C>A p.F385L | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV61704374; called by muse, mutect2, varscan2
- CNTN5 | c.2078C>A p.P693Q | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.631); catalogued as COSV54308039; called by muse, mutect2, varscan2
- CNTNAP2 | c.2098+1G>A p.X700_splice | Splice Site (SNP) | VAF 16/50 reads (32%) | catalogued as COSV62176988; called by muse, varscan2
- CNTNAP3 | c.2203T>C p.Y735H | Missense Mutation (SNP) | VAF 62/208 reads (30%) | SIFT tolerated (0.57); PolyPhen benign (0.022); catalogued as COSV99904482; called by muse, mutect2, varscan2
- COL1A1 | c.145G>A p.D49N | Missense Mutation (SNP) | VAF 99/218 reads (45%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV56804614, COSV56805195; called by muse, mutect2, varscan2
- CORIN | c.66C>A p.V22= | Splice Region (SNP) | VAF 23/68 reads (34%) | catalogued as COSV56691103; called by muse, mutect2, varscan2
- COX7B | c.212G>A p.R71K | Missense Mutation (SNP) | VAF 44/60 reads (73%) | SIFT tolerated (0.16); PolyPhen benign (0.092); catalogued as COSV64864591; called by muse, mutect2, varscan2
- CREB3L2 | c.1044G>A p.R348= | Splice Region (SNP) | VAF 27/74 reads (36%) | catalogued as rs750056999, COSV57794734, COSV57797536; called by muse, mutect2, varscan2
- CRYGD | c.392G>A p.W131* | Nonsense Mutation (SNP) | VAF 24/123 reads (20%) | catalogued as COSV100006013; called by muse, mutect2, varscan2
- CSMD3 | c.501G>T p.K167N | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.996); catalogued as COSV52104810; called by muse, mutect2
- CSTF1 | c.32G>A p.R11H | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); catalogued as rs1421239466, COSV53858263; called by muse, mutect2, varscan2
- CTSK | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 14/190 reads (7%) | SIFT tolerated (0.71); PolyPhen benign (0.005); catalogued as rs200515162, COSV55011869; ClinVar: uncertain significance; called by muse, mutect2
- CTTNBP2 | c.4578C>G p.D1526E | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV50399614; called by muse, mutect2, varscan2
- CUEDC1 | c.661G>T p.G221* | Nonsense Mutation (SNP) | VAF 8/78 reads (10%) | catalogued as rs372515433, COSV100804701; called by muse, mutect2, varscan2
- DBR1 | c.101T>A p.L34* | Nonsense Mutation (SNP) | VAF 14/28 reads (50%) | catalogued as COSV99604436; called by muse, mutect2, varscan2
- DCBLD1 | c.898G>C p.A300P | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV51640718; called by muse, mutect2, varscan2
- DCLK2 | c.1133-1G>T p.X378_splice | Splice Site (SNP) | VAF 32/57 reads (56%) | catalogued as COSV56203792; called by muse, mutect2, varscan2
- DDAH1 | c.239T>C p.V80A | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.49); PolyPhen benign (0.013); catalogued as COSV52303209; called by muse, mutect2, varscan2
- DDX46 | c.2041C>G p.R681G | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62799221; called by muse, mutect2, varscan2
- DEPDC5 | c.899C>T p.T300I | Missense Mutation (SNP) | VAF 47/215 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56696893; called by muse, mutect2, varscan2
- DHX9 | c.2783C>G p.A928G | Missense Mutation (SNP) | VAF 60/295 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as COSV62359430; called by muse, mutect2, varscan2
- DIS3 | c.2275G>A p.D759N | Missense Mutation (SNP) | VAF 30/45 reads (67%) | SIFT tolerated (0.24); PolyPhen benign (0.415); catalogued as COSV66706356; called by muse, mutect2, varscan2
- DLL3 | c.1513G>A p.V505M | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs111556824, COSV99218960; called by muse, varscan2
- DNAH5 | c.9138T>A p.D3046E | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as COSV54204644, COSV54222395; called by muse, mutect2, varscan2
- DNAJC21 | c.394G>A p.D132N | Missense Mutation (SNP) | VAF 36/151 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.218); catalogued as COSV57760496; called by muse, mutect2, varscan2
- DOP1A | c.2858G>A p.R953H | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.319); catalogued as rs536203538, COSV52709849; called by muse, mutect2, varscan2
- DOT1L | c.469G>A p.D157N | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67108395; called by muse, mutect2, varscan2
- DPYS | c.818T>C p.I273T | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.949); catalogued as rs1213281806, COSV60908374; called by muse, mutect2, varscan2
- DSC1 | c.172T>G p.S58A | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV57145373; called by muse, mutect2, varscan2
- EHD2 | c.1429G>T p.V477L | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV54408229; called by muse, mutect2, varscan2
- ELAVL2 | c.314T>G p.L105R | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV56361382; called by muse, mutect2, varscan2
- ELF4 | c.848G>C p.G283A | Missense Mutation (SNP) | VAF 84/97 reads (87%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); catalogued as COSV57452447; called by muse, mutect2, varscan2
- ELFN2 | c.1793G>A p.R598Q | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT tolerated (0.06); PolyPhen benign (0.32); catalogued as rs778030367, COSV68744512; called by muse, mutect2, varscan2
- EML2 | c.152C>T p.P51L | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758488963, COSV55599288; called by muse, mutect2, varscan2
- EPHA7 | c.614G>T p.C205F | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65169284; called by muse, mutect2, varscan2
- EPHB1 | c.268C>T p.R90C | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369940994; called by muse, mutect2, varscan2
- ERBIN | c.2045C>T p.S682F | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.823); catalogued as COSV52315584; called by muse, mutect2, varscan2
- ESRRB | c.179C>T p.P60L | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT deleterious (0.02); PolyPhen benign (0.101); catalogued as COSV55061210; called by muse, mutect2, varscan2
- EVPL | c.3834C>G p.N1278K | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.343); catalogued as COSV56910512; called by muse, mutect2, varscan2
- FAAP100 | c.1478G>A p.S493N | Missense Mutation (SNP) | VAF 60/94 reads (64%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as rs761033560, COSV59885237; called by muse, mutect2, varscan2
- FAM160B1 | c.2285C>G p.S762C | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV65088013; called by muse, mutect2, varscan2
- FAM184A | c.2769G>T p.R923S | Missense Mutation (SNP) | VAF 43/225 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58854126; called by muse, mutect2, varscan2
- FAM3C | c.594+2T>A p.X198_splice | Splice Site (SNP) | VAF 28/111 reads (25%) | catalogued as COSV63435521; called by muse, mutect2, varscan2
- FAM50B | c.824G>A p.R275H | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV66654539; called by muse, mutect2, varscan2
- FAM98A | c.280A>C p.T94P | Missense Mutation (SNP) | VAF 52/181 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.354); catalogued as COSV53210154; called by muse, mutect2, varscan2
- FANCL | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 49/124 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0.189); catalogued as COSV52074268; called by muse, mutect2, varscan2
- FAT2 | c.11212C>T p.H3738Y | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV55819126; called by muse, mutect2
- FAT2 | c.2468G>T p.G823V | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.575); catalogued as COSV55819134; called by muse, mutect2, varscan2
- FBXO11 | c.1448A>T p.E483V (on ENST00000403359 / NM_001190274.2; = p.E399V on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV57019159; called by muse, mutect2, varscan2
- FBXO42 | c.400T>C p.Y134H | Missense Mutation (SNP) | VAF 65/127 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65045498; called by muse, mutect2, varscan2
- FCHO1 | c.480G>C p.E160D | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.963); catalogued as COSV53182384; called by muse, mutect2, varscan2
- FEN1 | c.332T>C p.L111P | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as COSV57250782; called by muse, mutect2, varscan2
- FERMT3 | c.1495G>A p.E499K (on ENST00000279227 / NM_178443.3; = p.E495K on NM_031471.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.577); catalogued as rs199681648, COSV54178172; called by muse, mutect2, varscan2
- FLG2 | c.1373C>T p.S458F | Missense Mutation (SNP) | VAF 167/265 reads (63%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.496); catalogued as COSV66168481, COSV66173971; called by muse, mutect2, varscan2
- FLOT2 | c.838A>G p.K280E | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.52); catalogued as rs749252702, COSV67529025; called by muse, mutect2, varscan2
- FMO4 | c.524A>G p.E175G | Missense Mutation (SNP) | VAF 16/336 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.223); catalogued as rs904483581, COSV63001060; called by muse, mutect2
- FPR1 | c.388C>T p.P130S | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59051936; called by muse, mutect2, varscan2
- FUCA2 | c.478G>A p.D160N | Missense Mutation (SNP) | VAF 45/91 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.85); catalogued as COSV50020087; called by muse, mutect2, varscan2
- GALNT17 | c.1507C>G p.R503G | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.98); catalogued as COSV61161003, COSV61162853; called by muse, mutect2, varscan2
- GARRE1 | c.983G>A p.R328K | Missense Mutation (SNP) | VAF 61/149 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.152); catalogued as COSV55098975; called by muse, mutect2, varscan2
- GAS2L3 | c.2039A>G p.D680G | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.038); catalogued as COSV57157144; called by muse, mutect2, varscan2
- GCNT4 | c.517A>G p.K173E | Missense Mutation (SNP) | VAF 76/186 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.186); catalogued as rs771735282, COSV59280803; called by muse, mutect2, varscan2
- GHITM | c.353A>G p.Q118R | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as COSV64538476; called by muse, mutect2, varscan2
- GINM1 | c.614G>T p.S205I | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66389771; called by muse, mutect2, varscan2
- GIT1 | c.1611+1G>A p.X537_splice | Splice Site (SNP) | VAF 54/108 reads (50%) | catalogued as COSV56402361; called by muse, mutect2, varscan2
- GLRA1 | c.1030C>G p.R344G | Missense Mutation (SNP) | VAF 49/273 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.624); catalogued as CM043288, COSV51012212; called by muse, mutect2, varscan2
- GNA12 | c.1008_1019del p.D336_R340delinsE | In Frame Del (DEL) | VAF 17/42 reads (40%) | catalogued as COSV51740607; called by mutect2, pindel, varscan2
- GNG3 | c.217G>A p.A73T | Missense Mutation (SNP) | VAF 85/142 reads (60%) | SIFT tolerated (0.48); PolyPhen benign (0.012); catalogued as COSV53654997; called by muse, mutect2, varscan2
- GOLGA2 | c.2650C>T p.R884C | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as rs368175525; called by muse, mutect2, varscan2
- GPATCH8 | c.488A>G p.K163R | Missense Mutation (SNP) | VAF 64/147 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59194715; called by muse, mutect2, varscan2
- GPR161 | c.1181G>T p.G394V | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV54789928; called by muse, mutect2
- GPSM1 | c.703C>T p.R235C | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781980488, COSV61303960; called by muse, mutect2, varscan2
- GRIK4 | c.2803C>T p.P935S | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs1342617547, COSV101483575; called by muse, mutect2, varscan2
- GUCY1A2 | c.1028G>T p.G343V | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56485619; called by muse, mutect2, varscan2
- GYS2 | c.922G>T p.V308F | Missense Mutation (SNP) | VAF 45/69 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV53922949; called by muse, mutect2, varscan2
- HAVCR2 | c.650T>C p.L217P | Missense Mutation (SNP) | VAF 61/102 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV57152911; called by muse, mutect2, varscan2
- HCN1 | c.1199T>C p.L400P | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV57508596; called by muse, varscan2
- HDAC6 | c.778A>G p.T260A | Missense Mutation (SNP) | VAF 9/11 reads (82%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.814); catalogued as COSV100490689; called by muse, mutect2, varscan2
- HEG1 | c.3516A>G p.R1172= | Splice Region (SNP) | VAF 22/36 reads (61%) | catalogued as COSV100230302; called by muse, mutect2, varscan2
- HIPK2 | c.3551G>C p.G1184A | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.995); catalogued as COSV69209028; called by muse, mutect2
- HLA-DOA | c.165A>T p.E55D | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.038); catalogued as COSV57714153; called by muse, mutect2, varscan2
- HLA-DQB1 | c.535del p.I180Lfs*12 | Frame Shift Del (DEL) | VAF 14/56 reads (25%) | catalogued as rs751976368; called by mutect2, varscan2
- HSPA6 | c.218A>G p.K73R | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.338); catalogued as rs1174058116, COSV100554029; called by muse, mutect2
- HSPH1 | c.1099A>T p.N367Y | Missense Mutation (SNP) | VAF 9/280 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60711297; called by muse, mutect2
- IDH2 | c.1233G>T p.M411I | Missense Mutation (SNP) | VAF 27/187 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.833); catalogued as COSV51562946; called by muse, mutect2, varscan2
- IGDCC4 | c.3256C>T p.R1086W | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.232); catalogued as COSV61536702; called by muse, mutect2, varscan2
- IGF1 | c.107C>T p.A36V | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs775312813, COSV61032515; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IGFBP1 | c.463A>G p.I155V | Missense Mutation (SNP) | VAF 78/132 reads (59%) | SIFT tolerated (0.25); PolyPhen benign (0.038); catalogued as COSV51874630; called by muse, mutect2, varscan2
- IGSF10 | c.4168G>A p.V1390I | Missense Mutation (SNP) | VAF 70/204 reads (34%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV56784840, COSV56789349; called by muse, mutect2, varscan2
- IL22RA1 | c.1317C>A p.S439R | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV54628533; called by muse, mutect2, varscan2
- INAVA | c.943G>A p.E315K | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV66255768; called by muse, mutect2, varscan2
- INPP5F | c.1510A>G p.M504V | Missense Mutation (SNP) | VAF 52/99 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs1434119374, COSV62821192; called by muse, mutect2, varscan2
- IPO11 | c.1765G>C p.E589Q | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs765462427, COSV57575940; called by muse, mutect2, varscan2
- IPO9 | c.965C>A p.S322Y | Missense Mutation (SNP) | VAF 39/61 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.408); catalogued as COSV64233619; called by muse, mutect2, varscan2
- ITGB7 | c.1735C>A p.R579S | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV57238613; called by muse, mutect2, varscan2
- IVNS1ABP | c.1333C>T p.P445S | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as rs267598232, COSV62250965; called by muse, mutect2, varscan2
- KAAG1 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.039); catalogued as rs1283032961, COSV51239685, COSV99219713; called by muse, mutect2, varscan2
- KALRN | c.8584G>C p.D2862H (on ENST00000360013 / NM_001024660.4; = p.D1165H on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 67/119 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52255636; called by muse, mutect2, varscan2
- KCTD19 | c.1089C>G p.I363M | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58572710; called by muse, mutect2, varscan2
- KDR | c.3976C>T p.L1326F | Missense Mutation (SNP) | VAF 56/326 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs778737297, COSV55764326; called by muse, mutect2, varscan2
- KIAA1549 | c.2024C>T p.S675F | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); catalogued as COSV54313296; called by muse, mutect2, varscan2
- KIF5A | c.571C>T p.R191C | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769315791, COSV54054240; called by muse, mutect2, varscan2
- KLHL24 | c.1393G>T p.D465Y | Missense Mutation (SNP) | VAF 66/137 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); catalogued as COSV54426051; called by muse, mutect2, varscan2
- KRT16 | c.262G>A p.G88S | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.021); catalogued as COSV56967919; called by muse, mutect2, varscan2
- KRTAP20-1 | c.119G>A p.G40D | Missense Mutation (SNP) | VAF 75/135 reads (56%) | PolyPhen benign (0.111); catalogued as COSV58168311; called by muse, mutect2, varscan2
- KRTAP3-2 | c.184G>A p.V62M | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as rs147430362; called by muse, mutect2, varscan2
- LAMA2 | c.8836G>C p.G2946R | Missense Mutation (SNP) | VAF 51/236 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70346208; called by muse, mutect2, varscan2
- LRIT1 | c.971G>A p.G324E | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64512568; called by muse, mutect2, varscan2
- LRP1 | c.8626T>C p.W2876R | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV54510310; called by muse, mutect2, varscan2
- LRRC7 | c.3968G>C p.R1323T (on ENST00000651989 / NM_001370785.2; = p.R1290T on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV50450898, COSV99230393; called by muse, mutect2, varscan2
- LRRC74A | c.293T>C p.V98A | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.036); catalogued as COSV53609576; called by muse, mutect2, varscan2
- LTN1 | c.2980C>G p.L994V | Missense Mutation (SNP) | VAF 43/76 reads (57%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.732); catalogued as COSV63733696; called by muse, mutect2, varscan2
- MAGI3 | c.1360+1G>T p.X454_splice | Splice Site (SNP) | VAF 14/36 reads (39%) | catalogued as COSV100288531; called by muse, mutect2
- MAP2 | c.3028G>T p.A1010S | Missense Mutation (SNP) | VAF 46/95 reads (48%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.279); catalogued as COSV52289996; called by muse, mutect2, varscan2
- MAP3K10 | c.2570G>A p.R857H | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs368709344; called by muse, mutect2, varscan2
- MAP3K7CL | c.556C>T p.L186F | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54509262; called by muse, mutect2, varscan2
- MASP1 | c.1007T>C p.L336P | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV51459604; called by muse, mutect2, varscan2
- MASP1 | c.818A>G p.H273R | Missense Mutation (SNP) | VAF 118/360 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.131); catalogued as COSV51459627; called by muse, mutect2, varscan2
- MCM5 | c.19C>G p.P7A | Missense Mutation (SNP) | VAF 38/155 reads (25%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as rs764150043, COSV53346176; called by muse, mutect2, varscan2
- MCM7 | c.1902C>G p.I634M | Missense Mutation (SNP) | VAF 24/156 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.02); catalogued as COSV57996239; called by muse, mutect2, varscan2
- MED13L | c.2588G>A p.R863K | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0.259); catalogued as rs747479780, COSV56119381; called by muse, mutect2, varscan2
- MEGF8 | c.3311G>C p.R1104P (on ENST00000251268 / NM_001271938.2; = p.R1037P on NM_001410.3) | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99235244; called by muse, mutect2
- METTL3 | c.953A>T p.N318I | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV52968719; called by muse, mutect2, varscan2
- MINPP1 | c.1103T>G p.F368C | Missense Mutation (SNP) | VAF 8/135 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64354318; called by muse, mutect2
- MMP2 | c.260G>T p.G87V | Missense Mutation (SNP) | VAF 7/122 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54601032; called by muse, mutect2
- MMP27 | c.438del p.F146Lfs*12 | Frame Shift Del (DEL) | VAF 38/121 reads (31%) | catalogued as COSV52780722; called by mutect2, pindel, varscan2
- MORC3 | c.1897G>T p.D633Y | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); catalogued as COSV68688329; called by muse, mutect2, varscan2
- MOV10L1 | c.3110C>G p.P1037R | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV53170728; called by muse, mutect2, varscan2
- MTUS2 | c.56G>A p.R19K | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.096); catalogued as COSV70916614, COSV70916668; called by muse, mutect2, varscan2
- MTUS2 | c.296G>C p.R99T | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV70916670; called by muse, varscan2
- MTUS2 | c.450G>T p.R150S | Missense Mutation (SNP) | VAF 45/173 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.082); catalogued as COSV70916674; called by muse, varscan2
- MTUS2 | c.774G>C p.E258D | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.024); catalogued as COSV101462140; called by muse, mutect2
- MTUS2 | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs1348753784, COSV70916675; called by muse, mutect2, varscan2
- MUC5B | c.12214A>G p.S4072G | Missense Mutation (SNP) | VAF 72/123 reads (59%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV71591937; called by muse, mutect2, varscan2
- MYH11 | c.3722G>C p.R1241P | Missense Mutation (SNP) | VAF 81/250 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.677); catalogued as COSV55552191; called by muse, mutect2, varscan2
- MYH7 | c.3473C>T p.S1158F | Missense Mutation (SNP) | VAF 5/112 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); catalogued as COSV100805887; called by muse, mutect2
- NACC1 | c.100G>A p.V34M | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52834591, COSV99457360; called by muse, varscan2
- NAMPT | c.649G>A p.G217R | Missense Mutation (SNP) | VAF 66/107 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55994963, COSV99747962; called by muse, mutect2, varscan2
- NAPSA | c.1055G>A p.R352H | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.616); catalogued as rs747885843, COSV53796819; called by muse, mutect2, varscan2
- NCDN | c.232G>C p.D78H | Missense Mutation (SNP) | VAF 16/264 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as COSV57845467; called by muse, mutect2
- NCKAP5L | c.526G>T p.A176S | Missense Mutation (SNP) | VAF 21/33 reads (64%) | SIFT tolerated (1); PolyPhen benign (0.076); catalogued as rs1328973311, COSV60129370; called by muse, mutect2, varscan2
- NFASC | c.578A>G p.H193R (on ENST00000339876 / NM_001378329.1; = p.H187R on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/90 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV58364912; called by muse, mutect2, varscan2
- NKAIN2 | c.604C>T p.Q202* | Nonsense Mutation (SNP) | VAF 34/74 reads (46%) | catalogued as rs778762753, COSV100865412; called by muse, mutect2, varscan2
- NKX2-3 | c.620G>C p.R207P | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as rs765275806, COSV60728572; called by muse, varscan2
- NPAS4 | c.2161G>T p.D721Y | Missense Mutation (SNP) | VAF 30/158 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.123); catalogued as COSV60650303; called by muse, mutect2, varscan2
- NPBWR2 | c.995G>A p.R332Q | Missense Mutation (SNP) | VAF 30/49 reads (61%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs779684143, COSV100871139, COSV63900090; called by muse, mutect2, varscan2
- NSMCE2 | c.179G>T p.S60I | Missense Mutation (SNP) | VAF 55/372 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.737); catalogued as COSV54897718; called by muse, mutect2, varscan2
- NSMCE3 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0.01); catalogued as COSV54270394; called by muse, varscan2
- NTRK3 | c.157C>T p.L53F | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.7); PolyPhen benign (0.012); catalogued as COSV58120811, COSV58146628; called by muse, mutect2, varscan2
- NUDCD1 | c.95G>A p.C32Y | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as COSV53456052, COSV53456693; called by muse, mutect2, varscan2
- OR1G1 | c.148A>G p.I50V | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV61030150; called by muse, mutect2
- OR4K5 | c.176T>C p.M59T | Missense Mutation (SNP) | VAF 54/240 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as COSV60003409; called by muse, mutect2, varscan2
- OSBPL6 | c.2452A>T p.M818L | Missense Mutation (SNP) | VAF 45/77 reads (58%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV51916803; called by muse, mutect2, varscan2
- PACC1 | c.991A>G p.M331V | Missense Mutation (SNP) | VAF 83/105 reads (79%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.915); catalogued as COSV54787798; called by muse, mutect2, varscan2
- PAGE5 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as COSV56943538; called by muse, mutect2, varscan2
- PALMD | c.92T>C p.I31T | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.323); catalogued as rs754770377, COSV54164281; called by muse, mutect2, varscan2
- PALMD | c.567T>A p.S189R | Missense Mutation (SNP) | VAF 32/147 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV54164289; called by muse, mutect2, varscan2
- PAPLN | c.1355G>A p.G452D (on ENST00000554301; = p.G425D on NM_173462.4) | Missense Mutation (SNP) | VAF 69/97 reads (71%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.638); catalogued as rs770393234, COSV53717389; called by muse, mutect2, varscan2
- PARD6B | c.883G>T p.D295Y | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV65404411; called by muse, mutect2
- PCDH10 | c.680dup p.Q228Afs*18 | Frame Shift Ins (INS) | VAF 19/45 reads (42%) | catalogued as COSV52086878; called by mutect2, pindel, varscan2
- PCDHA13 | c.806C>G p.P269R | Missense Mutation (SNP) | VAF 78/186 reads (42%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.043); catalogued as COSV56498449; called by muse, mutect2, varscan2
- PCDHB15 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 41/184 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.025); catalogued as COSV50917588; called by muse, mutect2, varscan2
- PCF11 | c.276T>G p.F92L | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53530694; called by muse, mutect2, varscan2
- PCMTD1 | c.676G>A p.D226N | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.187); catalogued as COSV62121857; called by muse, mutect2, varscan2
- PIGS | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.87); PolyPhen benign (0.288); catalogued as COSV52024320; called by muse, mutect2, varscan2
- PITX2 | c.704C>G p.P235R (on ENST00000354925 / NM_001204397.1; = p.P242R on NM_000325.6) | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV60740837; called by muse, mutect2, varscan2
- PLCL1 | c.3091A>G p.I1031V | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.034); catalogued as rs776928438, COSV70830334; called by muse, mutect2, varscan2
- PLXNA1 | c.4477C>T p.L1493F | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52525772; called by muse, mutect2, varscan2
- POLR2B | c.1111A>T p.R371W | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58900211; called by muse, mutect2, varscan2
- PPARGC1A | c.2293+1G>T p.X765_splice | Splice Site (SNP) | VAF 17/58 reads (29%) | catalogued as COSV53527275; called by muse, mutect2, varscan2
- PQBP1 | c.250G>C p.V84L | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as COSV54430310, COSV54430624; called by muse, mutect2, varscan2
- PRAMEF1 | c.1373C>A p.P458H | Missense Mutation (SNP) | VAF 57/261 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60009068; called by muse, mutect2, varscan2
- PRDM16 | c.509A>G p.K170R | Missense Mutation (SNP) | VAF 61/173 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.396); catalogued as COSV54589108; called by muse, mutect2, varscan2
- PRDM9 | c.1681T>C p.F561L | Missense Mutation (SNP) | VAF 45/137 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as COSV57005908; called by muse, mutect2, varscan2
- PRKDC | c.4888G>A p.D1630N | Missense Mutation (SNP) | VAF 32/61 reads (52%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as COSV58051233; called by muse, mutect2, varscan2
- PSMD5 | c.931A>G p.M311V | Missense Mutation (SNP) | VAF 85/138 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); catalogued as COSV52960666; called by muse, mutect2, varscan2
- PTCHD3 | c.980A>G p.Y327C | Missense Mutation (SNP) | VAF 47/146 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV71256756; called by muse, mutect2, varscan2
- PTGFRN | c.884T>A p.L295Q | Missense Mutation (SNP) | VAF 33/139 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67798407; called by muse, mutect2, varscan2
- PTK2B | c.109G>T p.D37Y | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV57755712; called by muse, mutect2, varscan2
- PYM1 | c.580G>C p.E194Q | Missense Mutation (SNP) | VAF 53/363 reads (15%) | SIFT tolerated (0.67); PolyPhen benign (0.023); catalogued as COSV56811938; called by muse, mutect2, varscan2
- RAB39A | c.36C>G p.I12M | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV57694829; called by muse, mutect2, varscan2
- RAB40B | c.688G>C p.G230R | Missense Mutation (SNP) | VAF 29/201 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.714); catalogued as COSV53916003, COSV99483664; called by muse, mutect2, varscan2
- RAI14 | c.2261T>A p.L754H | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54293834; called by muse, mutect2, varscan2
- RAPH1 | c.1277A>T p.Y426F (on ENST00000319170 / NM_213589.3; = p.Y478F on NM_203365.4) | Missense Mutation (SNP) | VAF 88/169 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV57352901; called by muse, mutect2, varscan2
- RASSF6 | c.676A>G p.I226V (on ENST00000342081 / NM_201431.2; = p.I194V on NM_177532.5) | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as COSV56718377; called by muse, mutect2, varscan2
- RBBP6 | c.3378G>C p.K1126N | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.24); catalogued as COSV60504959; called by muse, mutect2, varscan2
- RBBP6 | c.5003A>G p.K1668R | Missense Mutation (SNP) | VAF 60/109 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.76); catalogued as COSV60504967; called by muse, mutect2, varscan2
- RIN3 | c.697T>C p.W233R | Missense Mutation (SNP) | VAF 89/106 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53648030; called by muse, mutect2, varscan2
- RNF123 | c.3644-1G>A p.X1215_splice | Splice Site (SNP) | VAF 59/94 reads (63%) | catalogued as COSV57538453; called by muse, mutect2, varscan2
- RNF19A | c.1438A>G p.I480V | Missense Mutation (SNP) | VAF 13/190 reads (7%) | SIFT tolerated (0.45); PolyPhen benign (0.011); catalogued as COSV61993075; called by muse, mutect2
- RP1L1 | c.6247G>A p.E2083K | Missense Mutation (SNP) | VAF 49/180 reads (27%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.026); catalogued as COSV66754638; called by muse, mutect2, varscan2
- RPF2 | c.704T>A p.L235H | Missense Mutation (SNP) | VAF 50/90 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV64369414; called by muse, mutect2, varscan2
- RRH | c.620A>T p.Y207F | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.615); catalogued as COSV58491325; called by muse, mutect2, varscan2
- RUNX1 | c.416G>C p.R139P (on ENST00000344691 / NM_001001890.3; = p.R166P on NM_001754.5) | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM992139, COSV55866502, COSV55867644, COSV55875824; called by muse, mutect2, varscan2
- RXFP1 | c.49+2T>C p.X17_splice | Splice Site (SNP) | VAF 4/23 reads (17%) | catalogued as COSV57049615; called by muse, mutect2, varscan2
- SCN10A | c.2992C>T p.P998S | Missense Mutation (SNP) | VAF 46/79 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV71861232; called by muse, mutect2, varscan2
- SEC22B | c.37G>A p.G13R | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1553230203; called by muse, mutect2, varscan2
- SEL1L2 | c.911G>C p.G304A | Missense Mutation (SNP) | VAF 46/105 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV53151906, COSV99532440; called by muse, mutect2, varscan2
- SELENON | c.724C>G p.P242A | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV62524699; called by muse, mutect2, varscan2
- SEMA3C | c.1348G>C p.G450R | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54845890, COSV99037473; called by muse, mutect2, varscan2
- SEPTIN8 | c.1285_1286+1del p.X429_splice | Splice Site (DEL) | VAF 11/90 reads (12%) | catalogued as rs778003168; called by pindel, varscan2
- SETBP1 | c.1553T>C p.L518P | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.731); catalogued as rs767337421, COSV56321203; called by muse, mutect2, varscan2
- SF3B2 | c.181-2A>G p.X61_splice | Splice Site (SNP) | VAF 131/274 reads (48%) | catalogued as rs1180364957, COSV59427877; called by muse, mutect2, varscan2
- SHROOM3 | c.2318A>G p.Q773R | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.462); catalogued as COSV56028519; called by muse, mutect2, varscan2
- SIRT7 | c.865C>T p.R289W | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs781647076, COSV58711213; called by muse, mutect2, varscan2
- SLC13A4 | c.826G>C p.A276P | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62460973; called by muse, mutect2, varscan2
- SLC25A46 | c.1138G>T p.E380* | Nonsense Mutation (SNP) | VAF 35/70 reads (50%) | catalogued as COSV100582561; called by muse, mutect2, varscan2
- SLC2A6 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 24/34 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64141865, COSV64142505; called by muse, mutect2, varscan2
- SLC35B1 | c.623A>G p.Y208C (on ENST00000649906; = p.Y171C on NM_005827.4) | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.818); catalogued as COSV53602963; called by muse, mutect2, varscan2
- SLC44A5 | c.590G>C p.S197T | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV63764204; called by muse, mutect2, varscan2
- SLC5A10 | c.500G>T p.W167L | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (0.32); PolyPhen benign (0.22); catalogued as COSV58757861; called by muse, mutect2, varscan2
- SLC7A14 | c.1067C>T p.P356L | Missense Mutation (SNP) | VAF 43/143 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371104588; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMC2 | c.1972G>C p.D658H | Missense Mutation (SNP) | VAF 7/131 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV53957779; called by muse, mutect2
- SMIM19 | c.140A>G p.K47R | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV69326855; called by muse, mutect2, varscan2
- SNRNP40 | c.475C>A p.P159T | Missense Mutation (SNP) | VAF 89/181 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.196); catalogued as COSV55277343; called by muse, mutect2, varscan2
- SNX16 | c.755A>G p.E252G | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.421); catalogued as rs1056034927, COSV62035041; called by muse, mutect2, varscan2
- SP1 | c.537C>A p.F179L (on ENST00000327443 / NM_138473.3; = p.F172L on NM_003109.1) | Missense Mutation (SNP) | VAF 55/175 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as COSV59402750; called by muse, mutect2, varscan2
- SPAG17 | c.712G>A p.A238T | Missense Mutation (SNP) | VAF 33/152 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs758810240, COSV60458203; called by muse, mutect2, varscan2
- SPHK2 | c.1253G>A p.R418H | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs771680188, COSV55337151; called by muse, mutect2, varscan2
- SPRR2A | c.35G>T p.C12F | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs777003384, COSV101198693, COSV101198727; called by muse, mutect2, varscan2
- SPTB | c.4018A>T p.M1340L | Missense Mutation (SNP) | VAF 80/114 reads (70%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV67631630; called by muse, mutect2, varscan2
- SPTBN5 | c.7020C>A p.S2340R | Missense Mutation (SNP) | VAF 140/165 reads (85%) | SIFT tolerated (0.17); PolyPhen benign (0.042); catalogued as COSV58020204; called by muse, mutect2, varscan2
- SRCAP | c.3091G>C p.E1031Q | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.522); catalogued as COSV52672128; called by muse, mutect2, varscan2
- SSH3 | c.1359C>A p.N453K | Missense Mutation (SNP) | VAF 37/55 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57384664; called by muse, mutect2, varscan2
- STAMBPL1 | c.1303C>A p.L435M | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV64222553; called by muse, mutect2, varscan2
- STAP1 | c.183G>T p.K61N | Missense Mutation (SNP) | VAF 46/239 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.149); catalogued as COSV55327541; called by muse, mutect2
- SYCP1 | c.870G>T p.E290D | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.187); catalogued as COSV65697141; called by muse, mutect2, varscan2
- TASOR2 | c.7286A>G p.Y2429C | Missense Mutation (SNP) | VAF 71/166 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.452); catalogued as rs769073915, COSV60167292; called by muse, mutect2, varscan2
- TBC1D2B | c.1154G>C p.R385P | Missense Mutation (SNP) | VAF 33/136 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV56041464; called by muse, mutect2, varscan2
- TCEAL8 | c.245T>C p.L82P | Missense Mutation (SNP) | VAF 36/48 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV63506474; called by muse, mutect2, varscan2
- TCERG1 | c.2674G>A p.E892K | Missense Mutation (SNP) | VAF 79/121 reads (65%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.622); catalogued as COSV57036846; called by muse, mutect2, varscan2
- TDP2 | c.967G>T p.A323S | Missense Mutation (SNP) | VAF 26/203 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.254); catalogued as COSV61967103; called by muse, mutect2, varscan2
- TENM2 | c.5481G>C p.Q1827H (on ENST00000518659 / NM_001122679.2; = p.Q1588H on NM_001080428.3) | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV69129163; called by muse, mutect2, varscan2
- TENM3 | c.3119T>C p.V1040A | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV69307091; called by muse, mutect2, varscan2
- THAP1 | c.179C>T p.P60L | Missense Mutation (SNP) | VAF 79/299 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.048); catalogued as COSV54273068; called by muse, mutect2, varscan2
- TLE2 | c.1099G>A p.V367M | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1488281092, COSV53579781; called by muse, mutect2, varscan2
- TLN1 | c.2087C>T p.S696L | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.03); catalogued as rs762426705, COSV59207116; called by muse, mutect2, varscan2
- TLR7 | c.148G>T p.D50Y | Missense Mutation (SNP) | VAF 47/70 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV66124235; called by muse, mutect2, varscan2
- TMEM179B | c.625G>A p.D209N | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.338); catalogued as COSV53668345; called by muse, mutect2, varscan2
- TMPRSS15 | c.80T>C p.I27T | Missense Mutation (SNP) | VAF 61/106 reads (58%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV53039319; called by muse, mutect2, varscan2
- TNS2 | c.1106A>G p.Y369C (on ENST00000314250 / NM_170754.4; = p.Y379C on NM_015319.2) | Missense Mutation (SNP) | VAF 48/107 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58577166; called by muse, mutect2, varscan2
- TPX2 | c.705C>G p.F235L | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.15); catalogued as COSV55919371; called by muse, mutect2
- TRAF3IP3 | c.1492T>C p.Y498H | Missense Mutation (SNP) | VAF 81/99 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1249377829, COSV50552516; called by muse, mutect2, varscan2
- TRIM62 | c.1048G>A p.V350I | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.995); catalogued as rs771712820, COSV52221243; called by muse, mutect2, varscan2
- TRPC4 | c.2771G>T p.G924V (on ENST00000379705 / NM_016179.4; = p.G929V on NM_003306.3) | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.077); catalogued as COSV58999192, COSV59001644; called by muse, mutect2, varscan2
- TRPC4 | c.2344G>A p.D782N (on ENST00000379705 / NM_016179.4; = p.D787N on NM_003306.3) | Missense Mutation (SNP) | VAF 23/151 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as COSV100156665, COSV58999204; called by muse, mutect2, varscan2
- TSPAN14 | c.404G>T p.R135L | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV59367949, COSV59368500; called by muse, mutect2, varscan2
- TSSK3 | c.560A>T p.D187V | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); catalogued as COSV61981997; called by muse, mutect2, varscan2
- TTN | c.77270G>T p.G25757V (on ENST00000591111; = p.G18333V on NM_003319.4) | Missense Mutation (SNP) | VAF 25/109 reads (23%) | PolyPhen probably damaging (1); catalogued as COSV60035082; called by muse, mutect2, varscan2
- TTN | c.77269G>A p.G25757S (on ENST00000591111; = p.G18333S on NM_003319.4) | Missense Mutation (SNP) | VAF 24/110 reads (22%) | PolyPhen probably damaging (0.999); catalogued as COSV60035128; called by muse, mutect2, varscan2
- TTN | c.20213G>A p.G6738E (on ENST00000591111; = p.G5811E on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/34 reads (26%) | PolyPhen possibly damaging (0.9); catalogued as COSV60035171; called by muse, mutect2, varscan2
- TUBB | c.827G>A p.R276H | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.827); catalogued as rs1296169114; called by muse, mutect2
- UGT1A5 | c.452C>G p.T151R | Missense Mutation (SNP) | VAF 133/359 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs1477253039, COSV59388388; called by muse, mutect2
- UPF3B | c.1385G>A p.G462E (on ENST00000276201 / NM_080632.3; = p.G449E on NM_023010.3) | Missense Mutation (SNP) | VAF 53/74 reads (72%) | SIFT tolerated (0.08); PolyPhen benign (0.095); catalogued as COSV52229940; called by muse, mutect2, varscan2
- UROC1 | c.187G>C p.E63Q | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52032763; called by muse, mutect2
- USP22 | c.1258C>T p.R420W | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV54946514; called by muse, mutect2, varscan2
- USP34 | c.668C>T p.S223F | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.675); catalogued as COSV68400987, COSV99063707; called by muse, mutect2, varscan2
- UTP6 | c.1665A>T p.E555D | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV55573240; called by muse, mutect2, varscan2
- UVRAG | c.1992G>C p.E664D | Missense Mutation (SNP) | VAF 47/59 reads (80%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.991); catalogued as COSV62103883; called by muse, mutect2, varscan2
- VPS13D | c.3869C>G p.S1290C | Missense Mutation (SNP) | VAF 12/251 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50636718; called by muse, mutect2
- VTA1 | c.890A>C p.K297T | Missense Mutation (SNP) | VAF 84/140 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62658818; called by muse, mutect2, varscan2
- WSB1 | c.895C>T p.P299S | Missense Mutation (SNP) | VAF 23/233 reads (10%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.997); catalogued as COSV52214474; called by muse, mutect2, varscan2
- XIAP | c.597G>T p.Q199H | Missense Mutation (SNP) | VAF 26/37 reads (70%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.97); catalogued as COSV63022279; called by muse, mutect2, varscan2
- ZC3HC1 | c.733C>G p.H245D | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.166); catalogued as COSV61298159; called by muse, mutect2, varscan2
- ZFP36L2 | c.695A>T p.D232V | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.328); catalogued as COSV56697946, COSV56700035; called by muse, mutect2, varscan2
- ZHX2 | c.2395G>C p.G799R | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.149); catalogued as COSV100073974, COSV58712967; called by muse, mutect2, varscan2
- ZKSCAN2 | c.2875A>G p.K959E | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV60156784; called by muse, mutect2, varscan2
- ZMIZ2 | c.962C>G p.S321C | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as COSV54807753; called by muse, mutect2, varscan2
- ZNF251 | c.1106G>A p.R369K | Missense Mutation (SNP) | VAF 12/137 reads (9%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.881); catalogued as COSV52957254, COSV52958375; called by muse, mutect2
- ZNF430 | c.910C>A p.L304I | Missense Mutation (SNP) | VAF 63/165 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV55109553; called by muse, mutect2, varscan2
- ZNF439 | c.955A>C p.T319P | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV58309414; called by muse, mutect2
- ZNF443 | c.542T>C p.L181S | Missense Mutation (SNP) | VAF 92/196 reads (47%) | SIFT tolerated (0.43); PolyPhen benign (0.033); catalogued as rs774084237, COSV56891606; called by muse, mutect2, varscan2
- ZNF528 | c.922C>G p.Q308E | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.052); catalogued as COSV64619230; called by muse, mutect2, varscan2
- ZNF529 | c.1439G>T p.C480F | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61900232; called by muse, mutect2, varscan2
- ZNF550 | c.647G>T p.W216L | Missense Mutation (SNP) | VAF 97/171 reads (57%) | SIFT tolerated (0.18); PolyPhen benign (0.281); catalogued as COSV57304974; called by muse, mutect2, varscan2
- ZNF587 | c.33G>A p.Q11= | Splice Region (SNP) | VAF 17/81 reads (21%) | catalogued as rs747921611, COSV57148333; called by muse, mutect2, varscan2
- ZNF587 | c.1193A>G p.H398R | Missense Mutation (SNP) | VAF 102/246 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760637486, COSV57148337; called by muse, mutect2, varscan2
- ZNF620 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV58820368; called by muse, mutect2, varscan2
- ZNF761 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 39/193 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.241); catalogued as COSV61888244; called by muse, mutect2, varscan2
- ZNF784 | c.91G>A p.D31N | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV100323099, COSV57595987; called by muse, mutect2, varscan2
- ZNF85 | c.745A>G p.K249E | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.32); catalogued as COSV60214453; called by muse, mutect2, varscan2
- ZNF91 | c.1783A>T p.I595F | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.833); catalogued as COSV56084131; called by muse, mutect2, varscan2
- ZSCAN18 | c.686G>T p.W229L | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53732862; called by muse, mutect2, varscan2
- ZUP1 | c.721C>T p.Q241* | Nonsense Mutation (SNP) | VAF 28/50 reads (56%) | catalogued as COSV100885047; called by muse, mutect2, varscan2
- ACACA | c.1826C>T p.S609L | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- ANKMY1 | c.438_446del p.E146_Q148del | In Frame Del (DEL) | VAF 13/39 reads (33%) | called by mutect2, pindel, varscan2
- ANKRD20A2P | c.2263G>A p.E755K | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.08); PolyPhen benign (0); called by mutect2, varscan2
- ARID1A | c.4412dup p.N1471Kfs*20 | Frame Shift Ins (INS) | VAF 39/80 reads (49%) | called by mutect2, pindel, varscan2
- C10orf90 | c.369_371dup p.P124dup | In Frame Ins (INS) | VAF 19/98 reads (19%) | called by mutect2, pindel, varscan2
- DSTYK | c.240_245del p.V81_A82del | In Frame Del (DEL) | VAF 8/21 reads (38%) | called by mutect2, varscan2
- EPS15L1 | c.1522_1535del p.L508Nfs*40 | Frame Shift Del (DEL) | VAF 9/82 reads (11%) | called by mutect2, pindel, varscan2
- FAM104A | c.15_25del p.A6Kfs*2 | Frame Shift Del (DEL) | VAF 14/56 reads (25%) | called by mutect2, pindel, varscan2
- FUZ | c.258_290del p.E87_R97del | In Frame Del (DEL) | VAF 8/57 reads (14%) | called by mutect2, pindel*
- GPR107 | c.1584+2_1584+5dup | Frame Shift Ins (INS) | VAF 4/26 reads (15%) | called by mutect2, pindel
- H4C1 | c.216_221del p.Y73_T74del | In Frame Del (DEL) | VAF 36/178 reads (20%) | called by mutect2, pindel, varscan2
- HOMER1 | c.4_5+15delinsA p.X2_splice | Splice Site (DEL) | VAF 12/91 reads (13%) | called by pindel, varscan2*
- KDM6A | c.4075_4085del p.Q1359Tfs*26 | Frame Shift Del (DEL) | VAF 36/53 reads (68%) | called by mutect2, pindel, varscan2
- KIR3DL1 | c.307C>T p.P103S | Missense Mutation (SNP) | VAF 89/210 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- MAPKAPK3 | c.31_37del p.G11Cfs*27 | Frame Shift Del (DEL) | VAF 13/22 reads (59%) | called by mutect2, pindel, varscan2
- METTL3 | c.1402_1413delinsA p.R468Nfs*30 | Frame Shift Del (DEL) | VAF 44/133 reads (33%) | called by pindel, varscan2*
- NACC1 | c.190_209del p.S64Gfs*87 | Frame Shift Del (DEL) | VAF 23/47 reads (49%) | called by pindel, varscan2
- PRAMEF8 | c.1069G>T p.D357Y | Missense Mutation (SNP) | VAF 37/210 reads (18%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRAMEF8 | c.1068G>C p.E356D | Missense Mutation (SNP) | VAF 37/214 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SLC30A5 | c.1710_1730del p.D571_S577del | In Frame Del (DEL) | VAF 5/32 reads (16%) | called by mutect2, pindel
- SPATA7 | c.1216-11_1225del p.X406_splice | Splice Site (DEL) | VAF 9/75 reads (12%) | called by mutect2, pindel
- STAG3L4 | n.719+1G>A | Splice Site (SNP) | VAF 29/245 reads (12%) | called by muse, mutect2, varscan2
- STK10 | c.814_825del p.K272_L275del | In Frame Del (DEL) | VAF 10/63 reads (16%) | called by mutect2, pindel, varscan2
- TBC1D3F | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 222/848 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.304); called by muse, mutect2, varscan2
- TOX3 | c.1629del p.I544Sfs*70 | Frame Shift Del (DEL) | VAF 13/25 reads (52%) | called by mutect2, varscan2
- TRIO | c.1166_1169dup p.C391Efs*50 | Frame Shift Ins (INS) | VAF 8/86 reads (9%) | called by mutect2, pindel
- WASHC2A | c.1997A>G p.E666G | Missense Mutation (SNP) | VAF 146/275 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF598 | c.2685_2709del p.L896Rfs*28 | Frame Shift Del (DEL) | VAF 14/167 reads (8%) | called by mutect2, pindel
- AARS1 | c.1149C>G p.L383= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as COSV55747287; called by muse, mutect2, varscan2
- ACACB | c.357G>T p.G119= | Silent (SNP) | VAF 101/200 reads (51%) | catalogued as COSV58133897; called by muse, mutect2, varscan2
- AGAP3 | c.147C>T p.A49= (on ENST00000622464; = p.A85= on NM_031946.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as COSV52543970; called by muse, mutect2, varscan2
- AK9 | c.867A>C p.L289= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV53421112; called by muse, mutect2, varscan2
- ARL13A | c.258T>C p.Y86= | Silent (SNP) | VAF 12/16 reads (75%) | catalogued as rs1453765760, COSV65880111; called by muse, mutect2, varscan2
- AS3MT | c.561T>C p.Y187= | Silent (SNP) | VAF 113/180 reads (63%) | catalogued as COSV54916784; called by muse, mutect2, varscan2
- ATP10A | c.2304C>T p.A768= | Silent (SNP) | VAF 29/42 reads (69%) | catalogued as rs187685205, COSV63516960; called by muse, mutect2, varscan2
- ATP6V1B1 | c.339A>G p.L113= | Silent (SNP) | VAF 42/98 reads (43%) | catalogued as COSV52269296; called by muse, mutect2, varscan2
- ATXN3L | c.699T>G p.L233= | Silent (SNP) | VAF 31/135 reads (23%) | catalogued as COSV66075656; called by muse, mutect2, varscan2
- BCAR3 | c.1431C>T p.I477= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as COSV53074784; called by muse, mutect2, varscan2
- BMP2 | c.111G>A p.S37= | Silent (SNP) | VAF 10/17 reads (59%) | catalogued as COSV66577780; called by muse, mutect2
- BOP1 | c.1398C>T p.P466= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as rs1025796495; called by muse, mutect2, varscan2
- BPTF | c.2328C>T p.I776= | Silent (SNP) | VAF 24/41 reads (59%) | catalogued as rs759197596, COSV58836608; called by muse, mutect2, varscan2
- C10orf71 | c.114G>A p.R38= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as COSV60507355; called by muse, mutect2, varscan2
- CACNA1E | c.5775C>T p.P1925= | Silent (SNP) | VAF 91/250 reads (36%) | catalogued as rs759244871, COSV62392996; called by muse, mutect2, varscan2
- CALB1 | c.687T>C p.N229= | Silent (SNP) | VAF 59/105 reads (56%) | catalogued as COSV55367364; called by muse, mutect2, varscan2
- CCDC81 | c.216C>T p.I72= | Silent (SNP) | VAF 45/118 reads (38%) | catalogued as COSV53576840; called by muse, mutect2, varscan2
- CDK13 | c.1413G>A p.A471= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as rs779234602, COSV51699496; ClinVar: likely benign; called by muse, mutect2, varscan2
- CDK6 | c.195G>A p.L65= | Silent (SNP) | VAF 3/9 reads (33%) | catalogued as COSV56008319; called by muse, mutect2
- CELA3B | c.117C>T p.S39= | Silent (SNP) | VAF 10/160 reads (6%) | catalogued as COSV61403911; called by muse, mutect2
- CIITA | c.1431C>T p.L477= | Silent (SNP) | VAF 26/147 reads (18%) | catalogued as rs756459269, COSV60856904; called by muse, mutect2, varscan2
- CKAP5 | c.1911C>T p.C637= | Silent (SNP) | VAF 47/63 reads (75%) | catalogued as COSV56367453; called by muse, mutect2, varscan2
- CLSPN | c.594A>T p.V198= | Silent (SNP) | VAF 55/209 reads (26%) | catalogued as COSV52050623; called by muse, mutect2, varscan2
- CMAS | c.984C>T p.A328= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as COSV57556542; called by muse, mutect2, varscan2
- CNBD1 | c.873T>A p.L291= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as COSV101582182; called by muse, mutect2
- DCTN1 | c.2208C>A p.A736= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as COSV62620411; called by muse, mutect2, varscan2
- DDB2 | c.786C>G p.S262= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as COSV57038261; called by muse, mutect2, varscan2
- DHX9 | c.2880C>G p.L960= | Silent (SNP) | VAF 36/147 reads (24%) | catalogued as COSV62359436; called by muse, varscan2
- DHX9 | c.3193C>T p.L1065= | Silent (SNP) | VAF 42/170 reads (25%) | catalogued as rs1334812914, COSV62359441; called by muse, varscan2
- DICER1 | c.5658A>T p.G1886= | Silent (SNP) | VAF 246/304 reads (81%) | catalogued as COSV58619369; called by muse, mutect2, varscan2
- DNAH9 | c.7149C>G p.G2383= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV52348228; called by muse, mutect2, varscan2
- DNAI1 | c.1395C>T p.L465= | Silent (SNP) | VAF 35/107 reads (33%) | catalogued as rs764446899, COSV54280803; called by muse, mutect2, varscan2
- DNAJC13 | c.3327C>T p.I1109= | Silent (SNP) | VAF 77/142 reads (54%) | catalogued as COSV53447845; called by muse, mutect2, varscan2
- DPPA3 | c.57C>T p.T19= | Silent (SNP) | VAF 22/31 reads (71%) | catalogued as COSV61503020; called by muse, mutect2, varscan2
- EIF4H | c.150T>G p.P50= | Silent (SNP) | VAF 53/180 reads (29%) | catalogued as COSV56082095; called by muse, mutect2, varscan2
- ELMOD3 | c.732C>T p.H244= | Silent (SNP) | VAF 20/38 reads (53%) | catalogued as rs1250663280, COSV59772519; called by muse, mutect2, varscan2
- EZH1 | c.912A>G p.K304= | Silent (SNP) | VAF 29/55 reads (53%) | catalogued as COSV70549324; called by muse, mutect2, varscan2
- FAM13B | c.2430G>A p.Q810= | Silent (SNP) | VAF 64/108 reads (59%) | catalogued as COSV50365960; called by muse, mutect2, varscan2
- FAM76B | c.471T>A p.S157= | Silent (SNP) | VAF 17/41 reads (41%) | catalogued as rs529745167, COSV62556453; called by muse, mutect2, varscan2
- FBH1 | c.3048C>T p.S1016= (on ENST00000362091 / NM_178150.3; = p.S1067= on NM_032807.4) | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as COSV62982463; called by muse, mutect2, varscan2
- FBXO38 | c.3294A>G p.P1098= (on ENST00000340253 / NM_205836.3; = p.P1023= on NM_030793.5) | Silent (SNP) | VAF 47/104 reads (45%) | catalogued as COSV57027494; called by muse, mutect2, varscan2
- GAK | c.2568G>A p.L856= | Silent (SNP) | VAF 44/92 reads (48%) | catalogued as COSV58504459; called by muse, mutect2, varscan2
- GDI1 | c.864G>A p.P288= | Silent (SNP) | VAF 32/111 reads (29%) | catalogued as rs782189540, COSV50131118; called by muse, mutect2, varscan2
- GFM2 | c.999G>C p.L333= | Silent (SNP) | VAF 19/112 reads (17%) | catalogued as COSV57190663; called by muse, mutect2, varscan2
- GGCX | c.1296A>G p.T432= | Silent (SNP) | VAF 40/178 reads (22%) | catalogued as COSV52088197; called by muse, mutect2, varscan2
- GNAI1 | c.978C>G p.A326= | Silent (SNP) | VAF 17/97 reads (18%) | catalogued as COSV63522797; called by muse, mutect2, varscan2
- HELZ2 | c.6708G>A p.R2236= (on ENST00000467148 / NM_001037335.2; = p.R1667= on NM_033405.3) | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as rs1420622195, COSV71295885; called by muse, mutect2, varscan2
- HEMGN | c.303G>A p.L101= | Silent (SNP) | VAF 30/115 reads (26%) | catalogued as rs898151041, COSV52326293; called by muse, mutect2, varscan2
- HERC2 | c.4773T>C p.N1591= | Silent (SNP) | VAF 47/99 reads (47%) | catalogued as COSV99872198; called by muse, mutect2, varscan2
- HRH2 | c.1068C>T p.A356= | Silent (SNP) | VAF 16/97 reads (16%) | catalogued as rs1477441521, COSV51574160; called by muse, mutect2, varscan2
- HSP90AB1 | c.258G>A p.L86= | Silent (SNP) | VAF 86/175 reads (49%) | catalogued as COSV62334416; called by muse, mutect2, varscan2
- HSPA6 | c.534C>A p.P178= | Silent (SNP) | VAF 15/108 reads (14%) | catalogued as COSV59060953; called by muse, mutect2, varscan2
- HYDIN | c.11676G>A p.V3892= | Silent (SNP) | VAF 17/26 reads (65%) | catalogued as COSV66638863; called by muse, mutect2, varscan2
- IFIT3 | c.999C>G p.S333= | Silent (SNP) | VAF 21/101 reads (21%) | catalogued as COSV51078420, COSV51078833; called by muse, mutect2, varscan2
- IGF2R | c.6351C>T p.F2117= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as COSV100807142; called by muse, mutect2, varscan2
- ITGA10 | c.2136T>G p.R712= | Silent (SNP) | VAF 32/204 reads (16%) | catalogued as COSV65197238; called by muse, mutect2, varscan2
- KIAA1549 | c.2025T>C p.S675= | Silent (SNP) | VAF 19/53 reads (36%) | catalogued as COSV54313277; called by muse, mutect2, varscan2
- KLHL9 | c.1074T>C p.Y358= | Silent (SNP) | VAF 18/82 reads (22%) | catalogued as rs1232673217, COSV62921551; called by muse, mutect2, varscan2
- KPTN | c.486C>T p.L162= | Silent (SNP) | VAF 8/12 reads (67%) | catalogued as COSV100583399; called by muse, mutect2, varscan2
- MAP4K2 | c.1536C>T p.L512= | Silent (SNP) | VAF 48/96 reads (50%) | catalogued as COSV53643001; called by muse, mutect2, varscan2
- MRM2 | c.480A>C p.T160= | Silent (SNP) | VAF 38/56 reads (68%) | catalogued as COSV54248069; called by muse, mutect2, varscan2
- MTUS2 | c.366G>A p.Q122= | Silent (SNP) | VAF 48/165 reads (29%) | catalogued as COSV70916672; called by muse, varscan2
- MYO5C | c.666A>G p.T222= | Silent (SNP) | VAF 25/63 reads (40%) | catalogued as COSV55905749; called by muse, mutect2, varscan2
- NCKAP5L | c.525A>T p.P175= | Silent (SNP) | VAF 21/32 reads (66%) | catalogued as COSV60129378; called by muse, mutect2, varscan2
- NES | c.1509G>A p.G503= | Silent (SNP) | VAF 43/240 reads (18%) | catalogued as COSV63960958; called by muse, mutect2, varscan2
- NEUROD1 | c.507T>A p.V169= | Silent (SNP) | VAF 42/92 reads (46%) | catalogued as COSV54549140; called by muse, mutect2, varscan2
- NIFK | c.522G>A p.K174= | Silent (SNP) | VAF 76/156 reads (49%) | catalogued as rs1454265110, COSV53534726; called by muse, mutect2, varscan2
- NOXA1 | c.831A>G p.K277= | Silent (SNP) | VAF 12/61 reads (20%) | catalogued as COSV58161829; called by muse, mutect2, varscan2
- NUDCD3 | c.249A>G p.E83= | Silent (SNP) | VAF 16/80 reads (20%) | catalogued as COSV62648784; called by muse, mutect2, varscan2
- OLFM3 | c.1365C>G p.A455= (on ENST00000338858 / NM_001288821.1; = p.A435= on NM_058170.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/93 reads (16%) | catalogued as COSV58798447; called by muse, mutect2, varscan2
- OLIG3 | c.531C>T p.S177= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as COSV100880318, COSV62988541; called by muse, mutect2, varscan2
- OR2M5 | c.801C>T p.S267= | Silent (SNP) | VAF 186/236 reads (79%) | catalogued as rs1352616444, COSV63546209; called by muse, mutect2, varscan2
- OR6Q1 | c.462G>A p.L154= | Silent (SNP) | VAF 19/133 reads (14%) | catalogued as COSV56932970; called by muse, mutect2, varscan2
- OTULINL | c.432G>T p.V144= | Silent (SNP) | VAF 25/89 reads (28%) | catalogued as COSV57034418; called by muse, mutect2
- PCDHGB2 | c.1152C>T p.C384= | Silent (SNP) | VAF 25/98 reads (26%) | catalogued as COSV53941995; called by muse, mutect2, varscan2
- PCLO | c.13020C>A p.T4340= | Silent (SNP) | VAF 16/69 reads (23%) | catalogued as COSV61633418; called by muse, mutect2, varscan2
- PCNT | c.3135C>G p.T1045= | Silent (SNP) | VAF 13/95 reads (14%) | catalogued as COSV64027729; called by muse, mutect2, varscan2
- PHTF1 | c.2004C>T p.T668= | Silent (SNP) | VAF 40/121 reads (33%) | catalogued as COSV63367425; called by muse, mutect2, varscan2
- PLA2G15 | c.51C>T p.L17= | Silent (SNP) | VAF 6/8 reads (75%) | catalogued as COSV99547154; called by muse, mutect2, varscan2
- PLA2G2F | c.537C>T p.V179= | Silent (SNP) | VAF 74/118 reads (63%) | catalogued as COSV64279960; called by muse, mutect2, varscan2
- PZP | c.1602A>G p.A534= | Silent (SNP) | VAF 22/53 reads (42%) | catalogued as COSV54359854; called by muse, mutect2, varscan2
- RETN | c.54C>T p.S18= | Silent (SNP) | VAF 49/185 reads (26%) | catalogued as COSV55568928; called by muse, mutect2, varscan2
- RNF169 | c.1107T>C p.P369= | Silent (SNP) | VAF 10/132 reads (8%) | catalogued as rs1315374822, COSV55132260; called by muse, mutect2
- RPRM | c.201C>T p.L67= | Silent (SNP) | VAF 25/55 reads (45%) | catalogued as COSV57988763; called by muse, mutect2, varscan2
- S100A13 | c.285C>T p.I95= | Silent (SNP) | VAF 60/252 reads (24%) | catalogued as COSV59884619; called by muse, mutect2, varscan2
- SCAF4 | c.3150T>C p.N1050= | Silent (SNP) | VAF 34/113 reads (30%) | catalogued as COSV54256061; called by muse, mutect2, varscan2
- SEC13 | c.381G>A p.G127= (on ENST00000350697 / NM_183352.3; = p.G130= on NM_030673.4) | Silent (SNP) | VAF 29/46 reads (63%) | catalogued as COSV61601625; called by muse, mutect2, varscan2
- SIPA1L3 | c.279G>A p.L93= | Silent (SNP) | VAF 22/85 reads (26%) | catalogued as COSV55910371; called by muse, mutect2, varscan2
- SLC35F1 | c.276A>G p.T92= | Silent (SNP) | VAF 92/180 reads (51%) | catalogued as COSV64502787; called by muse, mutect2, varscan2
- SORCS1 | c.441G>C p.P147= | Silent (SNP) | VAF 22/62 reads (35%) | catalogued as COSV53864069, COSV53896753, COSV99547254; called by muse, mutect2, varscan2
- STIM2 | c.1128G>A p.Q376= | Silent (SNP) | VAF 25/63 reads (40%) | catalogued as COSV52838698; called by muse, mutect2, varscan2
- SVIL | c.3042A>G p.E1014= (on ENST00000355867 / NM_021738.3; = p.E588= on NM_003174.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/76 reads (17%) | catalogued as COSV63443103; called by muse, mutect2, varscan2
- TCF25 | c.1767G>C p.S589= | Silent (SNP) | VAF 82/413 reads (20%) | catalogued as COSV54527371; called by muse, mutect2, varscan2
- TIMELESS | c.672T>C p.L224= | Silent (SNP) | VAF 46/127 reads (36%) | catalogued as rs1457066741, COSV57511196; called by muse, mutect2, varscan2
- TKFC | c.423C>T p.S141= | Silent (SNP) | VAF 82/124 reads (66%) | catalogued as rs1194564101, COSV67523590; called by muse, mutect2, varscan2
- TM9SF2 | c.96G>A p.R32= | Silent (SNP) | VAF 62/87 reads (71%) | catalogued as COSV63480872; called by muse, mutect2, varscan2
- TMEM123 | c.123T>C p.S41= | Silent (SNP) | VAF 100/256 reads (39%) | catalogued as COSV63443942; called by muse, mutect2, varscan2
- TRAPPC2L | c.15C>T p.I5= | Silent (SNP) | VAF 9/9 reads (100%) | catalogued as rs748351026, COSV51935815, COSV51936042; called by muse, mutect2, varscan2
- TRIM56 | c.1548C>T p.F516= | Silent (SNP) | VAF 87/131 reads (66%) | catalogued as rs373361866; called by muse, mutect2, varscan2
- TSPOAP1 | c.75T>C p.H25= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as rs549753964, COSV52108073; called by muse, mutect2, varscan2
- TTC3 | c.4932A>G p.V1644= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as COSV61289846; called by muse, mutect2, varscan2
- TTPAL | c.867A>G p.V289= | Silent (SNP) | VAF 19/103 reads (18%) | catalogued as COSV52828786; called by muse, mutect2, varscan2
- WDR62 | c.717C>T p.P239= | Silent (SNP) | VAF 30/84 reads (36%) | catalogued as COSV54334622; called by muse, mutect2, varscan2
- WNT9B | c.606G>A p.V202= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as rs1444371390, COSV51518344; called by muse, mutect2, varscan2
- ZFAT | c.162A>G p.T54= | Silent (SNP) | VAF 18/72 reads (25%) | catalogued as COSV64733743, COSV64738025; called by muse, mutect2, varscan2
- ZNF33B | c.1557T>C p.H519= | Silent (SNP) | VAF 82/105 reads (78%) | catalogued as rs970191807, COSV63942393; called by muse, mutect2, varscan2
- ZW10 | c.1104T>C p.T368= | Silent (SNP) | VAF 73/187 reads (39%) | catalogued as COSV52316365; called by muse, mutect2, varscan2
- C8orf86 | n.1066G>C | RNA (SNP) | VAF 15/321 reads (5%) | catalogued as COSV63935306; called by muse, mutect2
- MAPKAP1 | c.498+5473A>T | Intron (SNP) | VAF 18/33 reads (55%) | catalogued as COSV56367407; called by muse, mutect2, varscan2
- MIR410 | n.80C>T | RNA (SNP) | VAF 41/56 reads (73%) | catalogued as rs757198063; called by muse, mutect2, varscan2
- RBM44 | c.-98-2846T>C | Intron (SNP) | VAF 15/24 reads (63%) | catalogued as rs1209601068, COSV57629355; called by muse, mutect2, varscan2
- SZT2 | c.*549G>A | 3'UTR (SNP) | VAF 9/24 reads (38%) | catalogued as rs771574218, COSV100981248; called by muse, mutect2, varscan2
- UCHL5 | chr1:193059513 G>A | 5'Flank (SNP) | VAF 7/15 reads (47%) | catalogued as COSV66476352; called by muse, mutect2, varscan2
